Somatic mutation profile of tumor specimen TCGA-Q1-A5R3-01A (aliquot TCGA-Q1-A5R3-01A-11D-A28B-09) from TCGA case TCGA-Q1-A5R3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 56.3 years (20,574 days).
Specimen TCGA-Q1-A5R3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fb09231-da82-45bb-b353-48f289e04981.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A5R3-10B (Blood Derived Normal), aliquot TCGA-Q1-A5R3-10B-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50b78b66-b384-499e-9729-e0a1fb3ec408

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 47, Silent 15, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.974G>A p.R325H (on ENST00000399959; = p.R326H on NM_001356.5) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs797045025, CM158024, COSV101302329; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.4195C>T p.Q1399* (on ENST00000358273 / NM_001042492.3; = p.Q1378* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as rs1131691072, CM153422, COSV62200898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 57/81 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.2479G>A p.V827I | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750022384, COSV64601547; called by muse, mutect2, varscan2
- AKNA | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56312336; called by muse, mutect2, varscan2
- AL592490.1 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69425891; called by muse, mutect2, varscan2
- AL592490.1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV69425276, COSV69425902; called by muse, mutect2, varscan2
- ALS2 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV51886494; called by muse, mutect2, varscan2
- AMZ2 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV63082542, COSV63082823; called by muse, mutect2, varscan2
- ANK2 | c.10642G>C p.E3548Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV52157743; called by muse, mutect2, varscan2
- APOB | c.1566G>T p.M522I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV51933081; called by muse, mutect2, varscan2
- ATP11B | c.1837dup p.T613Nfs*7 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | catalogued as rs1560101433; called by mutect2, pindel, varscan2
- CBLB | c.2363A>G p.N788S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs373403352; called by muse, mutect2, varscan2
- CFAP46 | c.6973G>A p.D2325N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as rs751989297, COSV54151515; called by muse, mutect2, varscan2
- CLK1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs954072057, COSV58433296; called by muse, mutect2, varscan2
- CNOT6L | c.1660C>T p.R554W (on ENST00000504123 / NM_001286790.2; = p.R549W on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as rs369854208; called by muse, mutect2, varscan2
- CPAMD8 | c.4748G>A p.W1583* (on ENST00000651564; = p.W1536* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV71596476; called by muse, mutect2, varscan2
- CR2 | c.820A>T p.I274F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65505879; called by mutect2, varscan2
- DBR1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV53429578; called by muse, mutect2, varscan2
- DNAJC21 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57760298; called by muse, mutect2, varscan2
- EPB41L4B | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV65796542, COSV65796820; called by muse, mutect2, varscan2
- EPS8L1 | c.1414C>T p.P472S (on ENST00000201647 / NM_133180.3; = p.P345S on NM_017729.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52381614; called by muse, mutect2
- FAM135B | c.2861A>C p.Q954P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52720624; called by muse, mutect2, varscan2
- FAXC | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140144378, COSV67602024; called by muse, mutect2, varscan2
- FDPS | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV63114355; called by muse, mutect2, varscan2
- GATB | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369788751, COSV56130290; called by muse, mutect2, varscan2
- IQGAP3 | c.3232C>T p.L1078F | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV63250931; called by muse, mutect2, varscan2
- KMT2A | c.10688G>T p.S3563I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV63285050; called by muse, mutect2, varscan2
- MBNL2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV59120248; called by muse, mutect2, varscan2
- MED1 | c.575+1G>A p.X192_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV56124360; called by muse, mutect2, varscan2
- MEGF8 | c.5884G>A p.E1962K (on ENST00000251268 / NM_001271938.2; = p.E1895K on NM_001410.3) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs1454888198, COSV52079694; called by muse, mutect2, varscan2
- MYH13 | c.2942A>C p.N981T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as COSV52826548; called by muse, mutect2, varscan2
- NFIC | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV59411735; called by muse, varscan2
- PDZD4 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.746); catalogued as rs782403197, COSV51246444; called by muse, mutect2
- PIRT | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV74119881; called by muse, mutect2, varscan2
- PKD1 | c.9484C>T p.R3162C | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756923411, CM1111442, COSV51914766; called by muse, mutect2, varscan2
- PML | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV51445589; called by muse, mutect2, varscan2
- REN | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65817674, COSV65817736; called by muse, mutect2, varscan2
- RSKR | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56381782; called by muse, mutect2, varscan2
- RSPH6A | c.1722G>C p.E574D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as COSV55571313; called by muse, varscan2
- SELE | c.1681C>T p.L561F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1206180870, COSV60975079; called by muse, mutect2, varscan2
- SGSM2 | c.1901C>T p.S634L (on ENST00000426855 / NM_001098509.2; = p.S679L on NM_014853.3) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52157517; called by muse, varscan2
- SLAMF1 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs371704387; called by muse, mutect2, varscan2
- SLC16A3 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313045112, COSV58364396; called by muse, mutect2, varscan2
- SPNS1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs781243388, COSV57954522; called by muse, mutect2, varscan2
- TMCC2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs955983640, COSV58002742; called by muse, mutect2, varscan2
- TTN | c.92617G>C p.D30873H (on ENST00000591111; = p.D23449H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | PolyPhen possibly damaging (0.747); catalogued as COSV60010728, COSV60259709; called by muse, mutect2, varscan2
- ULK1 | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as rs202232188, COSV100416457; called by muse, varscan2
- USP33 | c.1444A>C p.T482P | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV62469132; called by muse, mutect2, varscan2
- WDR7 | c.3984T>A p.V1328= | Splice Region (SNP) | VAF 20/54 reads (37%) | catalogued as COSV54352031; called by muse, mutect2, varscan2
- ZNF521 | c.2665G>T p.D889Y | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64122525, COSV64126059; called by muse, mutect2, varscan2
- KIAA1217 | c.3477_3507del p.D1160Pfs*41 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- MAP3K1 | c.714_715del p.S239Cfs*61 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- RDM1 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ABCA3 | c.2598C>T p.S866= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs369127242; called by muse, mutect2, varscan2
- ADAMTS16 | c.1872C>T p.F624= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV56983992, COSV56998419; called by muse, mutect2, varscan2
- AFF2 | c.3345C>T p.R1115= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs200225379, COSV99661635; called by muse, mutect2, varscan2
- AHCY | c.408C>T p.T136= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs1182822736, COSV54153067; called by muse, mutect2, varscan2
- ASH2L | c.1152C>G p.A384= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV51699347; called by muse, mutect2, varscan2
- ATP10A | c.2520C>T p.S840= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs778530761, COSV63516591; called by muse, mutect2
- CAPN10 | c.1353C>T p.Y451= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs747760729, COSV54375448; called by muse, mutect2, varscan2
- DBF4 | c.1734G>C p.V578= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV55996626; called by muse, mutect2, varscan2
- EIF4A2 | c.867G>C p.L289= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV56216712; called by muse, mutect2, varscan2
- ERO1A | c.1260G>A p.L420= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67471076; called by muse, mutect2, varscan2
- KCNG1 | c.294C>T p.F98= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV65368909, COSV65370057; called by muse, mutect2, varscan2
- NUP62 | c.1380G>A p.T460= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs780484739, COSV61311898; called by muse, mutect2, varscan2
- OAS3 | c.2469C>T p.L823= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV57445362; called by muse, mutect2, varscan2
- SLC6A19 | c.1404C>T p.L468= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV58670905; called by muse, mutect2, varscan2
- TRIM49 | c.747A>G p.G249= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100315864; called by muse, mutect2, varscan2
